Somatic mutation profile of tumor specimen MP2PRT-PARTUB-TMP1-A (aliquot MP2PRT-PARTUB-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARTUB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (666 days).
Specimen MP2PRT-PARTUB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4e1bcfa-d521-4b3f-8e8a-4f40c1824fe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTUB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTUB-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cc6d7bb-9a44-49f3-a72b-d41e9141b77e

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 152/410 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNTN5 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 119/294 reads (40%) | catalogued as rs1207005340, COSV54319878, COSV99677656; called by muse, mutect2, varscan2
- DSCAML1 | c.652G>A p.V218I (on ENST00000321322; = p.V158I on NM_020693.4) | Missense Mutation (SNP) | VAF 127/373 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs779516792, COSV58382432; called by muse, mutect2, varscan2
- GREB1 | c.5834C>T p.T1945M | Missense Mutation (SNP) | VAF 119/277 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201471874, COSV52188655; called by muse, mutect2, varscan2
- KIF21A | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 10/352 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs992012618, COSV62766656; called by muse, mutect2
- TEAD4 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 74/691 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs151141907; called by mutect2, varscan2
- GAGE2E | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 68/1362 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- HSPA12A | c.1171del p.R391Gfs*11 | Frame Shift Del (DEL) | VAF 159/555 reads (29%) | called by mutect2, pindel, varscan2
- TKTL2 | c.1371G>A p.S457= | Silent (SNP) | VAF 126/501 reads (25%) | catalogued as rs775147166; called by muse, mutect2, varscan2
